Gene-level copy-number profile of tumor specimen TCGA-AC-A2BM-01A from TCGA case TCGA-AC-A2BM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.6 years (15,212 days).
Specimen TCGA-AC-A2BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.af345a5e-3793-4751-b412-333cf037cda8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A2BM-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6cbfd79-5554-49d5-b8cb-0ad5f4411dd9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,781; copy number 2: 11,041; copy number 3: 11,554; copy number 4: 28,246; copy number 5: 3,448; copy number 6: 3,131; copy number 7: 206; copy number 8: 202; copy number 10: 60; copy number 13: 45; copy number 16: 29; copy number 18: 9; copy number 25: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A2BM-01A-11D-A21P-01): tumor purity 0.58, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 209 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–35,796,550, 1 gene, copy number 13 (within-gene range 8–18): UNC5D.
- chr8:35,525,176–43,202,855, 168 genes, copy number 10–25 (within-gene range 6–25) (broad region; genes not listed).
- chr11:69,294,151–70,207,390, 27 genes, copy number 13: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr11:70,278,921–70,279,297, 1 gene, copy number 13: H2AZP4.
- chr11:70,283,955–70,284,070, 1 gene, copy number 13: MIR548K.
- chr11:130,040,365–130,428,609, 11 genes, copy number 13: AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8.

Autosomal genes at a single copy (total copy number 1): 1,781. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
